Somatic mutation profile of tumor specimen TCGA-HT-8109-01A (aliquot TCGA-HT-8109-01A-11D-2395-08) from TCGA case TCGA-HT-8109, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 64.3 years (23,486 days).
Specimen TCGA-HT-8109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e0d3a5f-3223-4c1d-af1c-394a1f78dd4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8109-10A (Blood Derived Normal), aliquot TCGA-HT-8109-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f23adfda-8aad-46e6-b430-c2467bd2610a

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADK | c.865A>G p.I289V (on ENST00000286621; = p.I272V on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs541758866, COSV54217840; called by muse, mutect2, varscan2
- ASIC5 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs745353708, COSV101611163, COSV73332867; called by muse, mutect2, varscan2
- DDIT3 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV56258323; called by muse, mutect2, varscan2
- DUOX2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs373620034; called by muse, mutect2, varscan2
- FAM83B | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 64/213 reads (30%) | catalogued as COSV60926254; called by muse, mutect2
- FFAR4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs763777982, COSV65179656; called by muse, mutect2
- GBGT1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759428295, COSV64410373; called by muse, mutect2, varscan2
- GDPD1 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52384329; called by muse, mutect2, varscan2
- HTR4 | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58803377; called by muse, mutect2, varscan2
- KCNA10 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190117605; called by muse, mutect2, varscan2
- MYO9A | c.4433T>A p.L1478* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | catalogued as COSV61851418, COSV61856824; called by muse, mutect2
- OGDHL | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757281565, COSV65101260; called by muse, mutect2, varscan2
- PRG4 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV63356394; called by muse, mutect2, varscan2
- SDR39U1 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.144); catalogued as COSV52163162; called by muse, mutect2, varscan2
- SMARCA4 | c.3058G>T p.D1020Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100758215, COSV60807493; called by muse, mutect2, varscan2
- SMARCD2 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56741611; called by mutect2, varscan2
- TACC1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 111/342 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV52528208; called by muse, mutect2, varscan2
- TAPBPL | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs765498209, COSV56948537; called by muse, mutect2
- TENM2 | c.6158A>G p.N2053S (on ENST00000518659 / NM_001122679.2; = p.N1814S on NM_001080428.3) | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs762990923, COSV69139752; called by muse, mutect2, varscan2
- TSBP1 | c.1319A>C p.K440T (on ENST00000617061; = p.K445T on NM_006781.5) | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV66660730; called by muse, mutect2
- ZNF490 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.762); catalogued as COSV61008948; called by muse, mutect2, varscan2
- ZNF681 | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68075506; called by muse, mutect2, varscan2
- ARID4B | c.2990_2996del p.I997Kfs*4 | Frame Shift Del (DEL) | VAF 57/134 reads (43%) | called by mutect2, pindel, varscan2
- KTI12 | c.569_575del p.P190Qfs*21 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | called by mutect2, pindel
- ATF7IP | c.3258T>C p.V1086= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV53776629; called by muse, mutect2
- DNAH5 | c.910T>C p.L304= | Silent (SNP) | VAF 29/260 reads (11%) | catalogued as rs754396098, COSV54248443; called by muse, mutect2, varscan2
- FAM120A | c.2964T>A p.V988= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV52910060; called by muse, mutect2, varscan2
- FBLN7 | c.1062C>T p.L354= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV55617207, COSV99735033; called by muse, mutect2
- FLT3 | c.1545T>C p.C515= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV54068120; called by muse, mutect2, varscan2
- FLT3 | c.1218T>C p.F406= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV54068127; called by muse, mutect2, varscan2
- HERC1 | c.6264G>A p.T2088= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as rs1467849789, COSV71249940; called by muse, mutect2, varscan2
- IL27RA | c.1005G>A p.T335= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs759299044, COSV54598765; called by muse, mutect2
- LOXL4 | c.1656G>A p.P552= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs376068066; called by muse, mutect2, varscan2
- OR13G1 | c.774C>A p.R258= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as COSV62945196; called by muse, mutect2, varscan2
- PALB2 | c.1602T>C p.S534= | Silent (SNP) | VAF 5/146 reads (3%) | catalogued as COSV55169738; called by muse, mutect2
- ATP6AP1L | n.1485T>G | RNA (SNP) | VAF 19/241 reads (8%) | catalogued as COSV66475520, COSV66475689; called by muse, mutect2
- ZNF271P | n.2246G>A | RNA (SNP) | VAF 15/47 reads (32%) | catalogued as rs1356259187; called by muse, mutect2, varscan2
